Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A71U, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A71U-01A (Primary Tumor).

Result Type: Surgical Pathology Report
Result Date:
Performed By:
Encounter Info:

Surgical Pathology Report

ICD O-3
Carcinoma, papillary renal
cell 8260/3
Site R Kidney NOS C64.9
JW 8/9/13

Surgical Pathology Report

Requested By:
DIAGNOSIS:

A. Right kidney, partial resection for tumor: Renal cell carcinoma, papillary type. See synoptic report below:

Synoptic Report:

Procedure/laterality: Right kidney, partial nephrectomy.
Histologic type: Papillary renal cell carcinoma.
Nuclear grade (Fuhrman, 1-4): 3.
Tumor size: 3 x 2.5 x 2.5 cm.
Tumor site: Right kidney.
Tumor focality: Unifocal.
Sarcomatoid features: Absent.
Tumor necrosis: Absent.
Microscopic tumor extension: Tumor does not extend through the renal capsule or involve perinephric tissue.
Surgical margins: Negative for tumor (sample received disrupted but inked margin sections are negative for tumor).
Lymph-vascular invasion: Not identified.
Lymph nodes: Not applicable.
Pathologic findings in nonneoplastic kidney: Kidney showing nondiagnostic findings.
Pathologic staging: TNM: pT1a; pNX.
Biorepository sample (if applicable): A4; Contains 2 tissue samples: One is 100% normal kidney. The second fragments is tumor (>90% of nucleated cells).
Block(s) containing malignancy suitable for additional testing: A1, A2

CLINICAL INFORMATION:
Right renal mass.

SPECIMEN(S):
A: Right renal mass

	Yes	No

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled "right renal mass," is a portion of kidney, 42 g including attached fat. The overall specimen dimensions are 5.5 x 4 x 3.5 cm. The portion of kidney is 3.5 x 3 x 3 cm. Bulging from the parenchymal margin is a friable yellow-tan mass, 3 x 2.5 x 2.5 cm in maximum dimension. The mass does not grossly extend through the overlying renal capsule. The renal capsule is inked black. The parenchymal margin surrounding the protruding mass is inked blue. Sampled in four cassettes labeled: A1) inked capsular surface and tumor; A2) inked parenchymal margin with adjacent bulging tumor; A3) sample of fat overlying renal capsule; A4) mirror images of sample submitted for research

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 5d92acc1-08b4-4bd9-bac0-955b5f8527c1 (TCGA-SX-A71U.BCD2D78B-8B18-4470-A22D-DE51D886F64B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).